Somatic mutation profile of tumor specimen TCGA-S9-A7IX-01A (aliquot TCGA-S9-A7IX-01A-12D-A34A-08) from TCGA case TCGA-S9-A7IX, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 57.8 years (21,095 days).
Specimen TCGA-S9-A7IX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6d24f58-fbec-43a6-b7bd-f260a265e022.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7IX-10A (Blood Derived Normal), aliquot TCGA-S9-A7IX-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc1b82b3-372c-49e7-af89-f4f7b7c883ec

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 21, Silent 6, Nonsense Mutation 2, In Frame Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 1432/1512 reads (95%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV51765770; called by muse, mutect2, varscan2
- ACTRT3 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100377363, COSV57755498; called by muse, mutect2, varscan2
- ANAPC5 | c.1259T>C p.I420T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.159); catalogued as COSV55843510; called by muse, mutect2, varscan2
- BNC2 | c.209T>G p.L70* | Nonsense Mutation (SNP) | VAF 40/113 reads (35%) | catalogued as COSV101032505; called by muse, mutect2, varscan2
- BRCA2 | c.6157T>C p.S2053P | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as rs562893642, COSV101204021; called by muse, mutect2, varscan2
- CLEC12A | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as rs185029317, COSV100429421, COSV58561819; called by muse, mutect2, varscan2
- FCGRT | c.975_977del p.R325del | In Frame Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs773899345; called by pindel, varscan2
- FLNC | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1554396410, COSV100367578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GIT1 | c.761+1G>A p.X254_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99838014; called by muse, mutect2, varscan2
- IGF1R | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1013771934, COSV51340599; called by muse, mutect2, varscan2
- KCTD1 | c.363G>C p.L121F | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV100517553; called by muse, mutect2
- LTN1 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100797922; called by muse, mutect2, varscan2
- NEXMIF | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99280114; called by muse, mutect2, varscan2
- NPHP1 | c.1463G>A p.C488Y (on ENST00000393272 / NM_207181.4; = p.C489Y on NM_000272.5) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100337885; called by muse, mutect2, varscan2
- PCDHB3 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs1554272641, COSV99164395; called by muse, mutect2, varscan2
- PGBD4 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV99854766; called by muse, mutect2, varscan2
- PTPRC | c.2470G>C p.V824L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100722276; called by muse, mutect2, varscan2
- SEC14L5 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs767906101, COSV52041749; called by muse, mutect2, varscan2
- SLC38A10 | c.2917C>A p.Q973K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV66101337; called by muse, mutect2
- STK11IP | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs777415481, COSV99822470; called by muse, mutect2, varscan2
- TGFBR3 | c.1765G>A p.G589R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as rs777102917, COSV53031591; called by muse, mutect2, varscan2
- TLL2 | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV63575134; called by muse, mutect2, varscan2
- TRPC4 | c.2047A>T p.R683* | Nonsense Mutation (SNP) | VAF 32/73 reads (44%) | catalogued as COSV100156236; called by muse, mutect2, varscan2
- TTN | c.101554A>T p.T33852S (on ENST00000591111; = p.T26428S on NM_003319.4) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | PolyPhen possibly damaging (0.879); catalogued as COSV100600636; called by muse, mutect2, varscan2
- UGT2B4 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as rs200320318, COSV59316006; called by muse, mutect2, varscan2
- NF1 | c.3791_3793del p.E1264del | In Frame Del (DEL) | VAF 60/236 reads (25%) | called by pindel, varscan2
- GRM4 | c.576C>T p.Y192= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs368672368; called by muse, mutect2, varscan2
- H3C13 | c.366C>G p.P122= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV100516055; called by muse, mutect2, varscan2
- MAST2 | c.390G>A p.S130= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs558908632, COSV63618314; called by muse, mutect2, varscan2
- OR4D9 | c.357G>A p.A119= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs373390910; called by muse, mutect2
- TAS2R9 | c.279T>C p.N93= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs751159405, COSV99553661; called by muse, mutect2, varscan2
- TBX19 | c.1278G>A p.S426= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs200161002, COSV63197476; called by muse, mutect2, varscan2
